CCDI case PBBXKP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/99ba1b25-130a-4118-8262-7bb6049e4220

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 6.2 years (2,253 days).

Biospecimens (3 samples)
- Sample 0DJXPB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJXPS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJXRL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
